CCDI case PBBVZG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/bdac1079-d821-4d70-ad6a-f253b5098980

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin of upper limb and shoulder; Age at diagnosis: 1.3 years (493 days).

Biospecimens (3 samples)
- Sample 0DIY5W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIY63: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIY6D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
